Surgical pathology report (de-identified scan), TCGA case TCGA-N9-A4Q4, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MD Anderson, specimen TCGA-N9-A4Q4-01A (Primary Tumor).

[page 1 of 5]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) CERVIX, UTERUS, BILATERAL TUBES AND OVARIES:
ENDOMETRIAL MALIGNANT MIXED MULLERIAN TUMOR (MMMT) (SEE COMMENT).
TUMOR INVADES SUPERFICIAL MYOMETRIUM (1 MM/12 MM).
No lymphovascular invasion identified.
Myometrium with benign leiomyomata.
Cervix, bilateral ovaries and fallopian tubes with no pathologic abnormality.
- (B) LEFT COMMON ILIAC LYMPH NODE:
Two lymph nodes with no tumor present (0/2).
- (C) LEFT PELVIC LYMPH NODES:
Two lymph nodes with no tumor present.
- (D) RIGHT PELVIC LYMPH NODES:
Two lymph nodes with no tumor present (0/2).
- (E) RIGHT COMMON ILIAC LYMPH NODES:
METASTATIC CARCINOMA IDENTIFIED IN ONE OF ONE LYMPH NODE (1/1).
- (F) RIGHT GONADAL VESSEL:
Vascular tissue with no tumor present.
Portion of specimen pending decalcification, with addendum report to follow.
- (G) RIGHT PERIAORTIC LYMPH NODE:
Nine lymph nodes with no tumor present (0/9).
- (H) RIGHT PRESACRAL LYMPH NODE:
One lymph node, no tumor present (0/1).
- (I) OMENTUM:
Fibroadipose tissue with no tumor present.
- (J) INFRAGASTRIC OMENTAL NODULE:
One lymph node, no tumor present (0/1).

ICD-0-3
Mixed Mullerian Tumor
8950/3
Site: Uterus, NOS CSS.9
Copied AUS 1/16/13

COMMENT

The carcinomatous components include mixed high grade endometrioid and high grade serous carcinoma, while the sarcomatous component is undifferentiated with extensive rhabdoid features.

GROSS DESCRIPTION

(A) CERVIX, UTERUS, BILATERAL TUBES AND OVARIES – A hysterectomy and bilateral salpingo-oophorectomy, consisting of a uterus (12 x 5 x 3 cm), right ovary (2.5 x 2 x 1 cm), right fallopian tube (3 x 1 cm), left ovary (2.4 x 1 x 1 cm) and left fallopian tube (5 x 1 cm).

Filling the entire endometrial cavity is a polypoid tumor (8 x 4.5 x 3.5 cm), with a homogenous, fleshy, pink-white, focally necrotic cut surface. The tumor appears confined to the endometrium without myometrial or cervical involvement.

Two myometrial nodules (3.5 x 2 x 2 cm and 2.5 x 2 x 1.5 cm) are identified within the uterus and lower uterine segment, respectively. Both nodules have well-circumscribed borders and firm, whorled and bulging, gray-white cut surfaces. The remaining endometrium is irregular and trabeculated.

The remainder of the cervix and bilateral adnexa are unremarkable.

Representative portions of the specimen are submitted for tissue banking.

Representative sections are submitted.

[page 2 of 5]
SECTION CODE: A1, anterior cervix; A2, posterior cervix; A3-A5, tumor with underlying endomyometrium; A6-A8, tumor; A9, anterior endomyometrium, full thickness; A10, A11, posterior endomyometrium (A10 full thickness); A12, A13, anterior and posterior lower uterine segment, respectively; A14, right ovary and fallopian tube; A15, left ovary and fallopian tube; A16, A17, nodules (A17, lower uterine segment).

(B) LEFT COMMON ILIAC LYMPH NODE – Two lymph nodes (1.1 and 2.4 cm in greatest dimension). Submitted in toto in B.

(C) LEFT PELVIC LYMPH NODE – Multiple fibroadipose tissue fragments (5.9 x 4.5 x 0.7 cm). Multiple lymph nodes ranging from 1.0 to 5.5 cm in greatest dimension, are identified and submitted in toto.

SECTION CODE: C1, one lymph node; C2, one lymph node, bisected; C3-C5, one lymph node serially sectioned.

(D) RIGHT PELVIC LYMPH NODES – Two fibroadipose tissue fragments (4 x 3 x 0.6 cm). Two lymph nodes (1.3 and 4.8 cm in dimension) are identified and submitted in toto.

SECTION CODE: D1, one lymph node, bisected; D2, D3, one lymph node, bisected.

(E) RIGHT COMMON ILIAC LYMPH NODES – One lymph node (3 x 1 x 0.6 cm). Bisected and submitted in toto in E1, E2.

(F) RIGHT GONADAL VESSEL – A (4.5 cm in length x 0.3 cm in circumference) vasculature structure with surrounding connective tissue, no gross lesions are identified. A calcified nodule is identified within the lumen measuring (0.4 x 0.3 x 0.2 cm), submitted for decalcification.

SECTION CODE: F1, representative sections of the vascular structure; F2, representative sections from the vascular structure and surrounding connective tissue.

F3, calcified nodule.

(G) RIGHT PERIAORTIC LYMPH NODE – Multiple lymph nodes are identified, the largest measures 2.5 x 1.3 x 0.4 cm with pink-tan color and soft consistency. All lymph nodes are entirely submitted.

SECTION CODE: G1, three possible lymph nodes; G2, three possible lymph nodes; G3, two possible lymph nodes; G4, one possible lymph node.

(H) RIGHT PRESACRAL LYMPH NODE – Two pink-tan soft tissue fragments measuring on average (0.7 x 0.5 x 0.2 cm). Entirely submitted in H.

(I) OMENTUM – No gross lesions are identified. Representative sections are submitted in I1-I6.

(J) INFRA-GASTRIC OMENTAL NODULE – A (2.5 x 1.3 x 0.5 cm) yellow-tan fatty tissue with a pink-tan firm well-circumscribed nodule, measuring (0.7 x 0.3 x 0.3 cm). Entirely submitted in J.

CLINICAL HISTORY

Biphasic tumor of uterus

SNOMED CODES

T-83020, T-C4600, M-89503, M-89506

"Some tests reported here may have been developed and performance characteristics determined specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

these tests have not been

Start of ADDENDUM #1

[page 3 of 5]
ADDENDUM

This modified report is being issued to report the results of decalcification.

For specimen F (right gonadal vessel), the decalcified sections show a calcified vessel with no tumor present.

Entire report and diagnosis completed by:

Start of ADDENDUM #2

[page 4 of 5]
ADDENDUM

This modified report is being issued to provide additional information/results.

DIAGNOSIS

(C) LEFT PELVIC LYMPH NODES:

Ten lymph nodes, no tumor present.

(D) RIGHT PELVIC LYMPH NODES:

Eleven lymph nodes, no tumor present.

COMMENT

Additional examination revealed that there are ten lymph nodes on the right side in specimen C and there are 11 pelvic lymph nodes in D.

was notified of the change in lymph node number on

Entire report and diagnosis completed b

Start of ADDENDUM #3

[page 5 of 5]
ADDENDUM #3

This modified report is being issued to amend the diagnosis for part E.

DIAGNOSIS

(E) RIGHT COMMON ILIAC LYMPH NODES:

METASTATIC SARCOMA INVOLVING ONE LYMPH NODE. (SEE COMMENT)

COMMENT

The 0.4 cm focus of metastasis in the right common iliac lymph node consists of epithelioid cells with rhabdoid morphology. The cells are negative for keratin cocktail and strongly positive for desmin by immunohistochemistry. This is consistent with metastasis of the rhabdomyosarcoma component of the MMT.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Preliminary: 10/10/12 LW

EW 10/15/12

Source: NCI Genomic Data Commons file c1050aea-7523-4f68-8281-eadeeb49e410 (TCGA-N9-A4Q4.502B9D8B-51F7-4DD0-9BDA-79AACEB2AC21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).